CCDI case PBCNEI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/1bdcc2eb-fec8-429a-949c-e10a8dc219be

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Age at diagnosis: 5.6 years (2,042 days).

Biospecimens (2 samples)
- Sample 0DVSBZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVSCF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
